Somatic mutation profile of tumor specimen TCGA-56-7730-01A (aliquot TCGA-56-7730-01A-11D-2122-08) from TCGA case TCGA-56-7730, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.1 years (26,699 days).
Specimen TCGA-56-7730-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1264bf2-864a-4eaf-9811-b427da9b7f7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7730-11A (Solid Tissue Normal), aliquot TCGA-56-7730-11A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/835ab901-8f32-4922-ae8f-749a5b84e181

The open-access MAF lists 397 somatic variants for this specimen: 314 protein-altering or splice-affecting, 77 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 268, Silent 77, Nonsense Mutation 23, Frame Shift Del 9, Splice Site 7, Frame Shift Ins 3, Intron 3, 5'UTR 2, Splice Region 2, Translation Start Site 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 62/101 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1239977417, COSV99285894; called by muse, mutect2, varscan2
- ACAN | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755834901, COSV100718187; called by muse, varscan2
- ACSM2A | c.1656G>T p.K552N (on ENST00000219054; = p.K473N on NM_001308169.2) | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99525293; called by muse, mutect2, varscan2
- ACSM4 | c.1254A>T p.E418D | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101257158; called by muse, mutect2, varscan2
- ACSS3 | c.312-1G>T p.X104_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV54100489, COSV99698892; called by muse, mutect2, varscan2
- ACTR10 | c.78-2A>T p.X26_splice | Splice Site (SNP) | VAF 63/132 reads (48%) | catalogued as COSV99581170; called by muse, mutect2, varscan2
- ADAM10 | c.1849A>G p.R617G | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99546145; called by muse, mutect2, varscan2
- ADAM18 | c.1845A>T p.R615S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99695613; called by muse, mutect2, varscan2
- ADCY10 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100896887; called by muse, mutect2, varscan2
- ADCY6 | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 49/97 reads (51%) | catalogued as rs957124338, COSV100326648; called by muse, mutect2, varscan2
- ADCY8 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755362129, COSV99652501; called by muse, mutect2, varscan2
- ADGRA3 | c.3657G>T p.R1219S | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.601); catalogued as COSV99293328; called by muse, mutect2, varscan2
- ADGRF5 | c.397T>G p.C133G | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99345686; called by muse, mutect2, varscan2
- AHCTF1 | c.2399A>T p.D800V (on ENST00000366508; = p.D774V on NM_015446.5) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100403776; called by muse, mutect2, varscan2
- AL592490.1 | c.665C>A p.A222E | Missense Mutation (SNP) | VAF 63/85 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs894877855, COSV101308208; called by muse, mutect2, varscan2
- ANGPT2 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as rs1340794985, COSV100290928; called by muse, mutect2
- ANGPT2 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1409252918, COSV100290931; called by muse, mutect2, varscan2
- ANK2 | c.3577C>T p.R1193C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148287474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.11383A>T p.S3795C | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV52181606; called by muse, mutect2, varscan2
- ANO10 | c.134A>T p.D45V | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as COSV52732443; called by muse, mutect2, varscan2
- ARFGEF2 | c.2223G>C p.K741N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352414182, COSV64214534; called by muse, mutect2, varscan2
- ASCC3 | c.3579G>T p.R1193S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100225815; called by muse, mutect2, varscan2
- ASH1L | c.7423C>T p.P2475S (on ENST00000368346 / NM_001366177.2; = p.P2470S on NM_018489.3) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100853436; called by muse, mutect2, varscan2
- ATP13A5 | c.1427T>C p.M476T | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs966029195, COSV60877511; called by muse, mutect2, varscan2
- ATRX | c.3416A>T p.N1139I | Missense Mutation (SNP) | VAF 77/90 reads (86%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as COSV100970828; called by muse, mutect2, varscan2
- BANK1 | c.1169G>C p.G390A | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536381; called by muse, mutect2, varscan2
- BCOR | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100653367; called by muse, mutect2, varscan2
- BPIFB4 | c.675G>A p.T225= | Splice Region (SNP) | VAF 11/62 reads (18%) | catalogued as rs779617450, COSV64950696, COSV64950757; called by muse, mutect2, varscan2
- BRINP1 | c.664del p.E222Rfs*11 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as COSV56305130; called by mutect2, pindel, varscan2
- C10orf82 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100980116; called by muse, mutect2, varscan2
- C7orf25 | c.1067G>T p.S356I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as COSV100623644; called by muse, mutect2, varscan2
- CACNG3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs753398983, COSV99136279; called by muse, mutect2, varscan2
- CAPN5 | c.1771T>C p.S591P (on ENST00000456580; = p.S551P on NM_004055.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99582197; called by muse, mutect2
- CCDC59 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99810685; called by muse, mutect2, varscan2
- CCDC73 | c.1097C>G p.S366* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100067569; called by muse, mutect2, varscan2
- CCDC86 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV99920147; called by muse, mutect2, varscan2
- CD163 | c.2482A>T p.S828C | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100775863; called by muse, mutect2, varscan2
- CD37 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100115014; called by muse, mutect2, varscan2
- CDH18 | c.1214T>A p.V405D | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99935286; called by muse, mutect2, varscan2
- CDHR5 | c.1805G>T p.G602V (on ENST00000358353 / NM_001171968.2; = p.G608V on NM_021924.5) | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100363505; called by muse, mutect2, varscan2
- CDKL5 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 76/91 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV101184339; called by muse, mutect2, varscan2
- CEP135 | c.3346C>T p.R1116* | Nonsense Mutation (SNP) | VAF 155/206 reads (75%) | catalogued as rs953311582, COSV99954471; called by muse, mutect2, varscan2
- CEP164 | c.4072G>T p.E1358* | Nonsense Mutation (SNP) | VAF 44/96 reads (46%) | catalogued as COSV99633435; called by muse, mutect2, varscan2
- CEP97 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV100511781; called by muse, varscan2
- CHAC2 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99712066; called by muse, mutect2, varscan2
- CHCHD2 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV101271047; called by muse, mutect2, varscan2
- CLEC6A | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101165653; called by muse, mutect2, varscan2
- CMYA5 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV101484087, COSV101484137; called by muse, mutect2, varscan2
- CNGB1 | c.1964T>C p.M655T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99202589; called by muse, mutect2, varscan2
- CNR1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs756153990, COSV100759231; called by muse, mutect2, varscan2
- CNTN3 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1016109917, COSV55163762; called by muse, mutect2, varscan2
- CNTN6 | c.2686G>T p.V896F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV100610789; called by muse, mutect2, varscan2
- COL8A2 | c.970A>T p.K324* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | catalogued as COSV100291208; called by muse, mutect2, varscan2
- CRAMP1 | c.1705C>G p.Q569E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV99246036; called by muse, mutect2, varscan2
- CREB3L3 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99314186; called by muse, mutect2, varscan2
- CSMD3 | c.9824G>C p.G3275A (on ENST00000297405 / NM_001363185.1; = p.G3106A on NM_052900.3) | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV52158742, COSV99835522; called by muse, mutect2, varscan2
- CYP1A1 | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101122312; called by muse, mutect2, varscan2
- CYP2C8 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100987946, COSV64879125; called by muse, mutect2, varscan2
- DACH2 | c.1519G>T p.V507F | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV100913305; called by muse, mutect2, varscan2
- DDHD1 | c.1919C>G p.T640R (on ENST00000323669; = p.T837R on NM_030637.3) | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100079591, COSV100080252, COSV60359179; called by muse, mutect2, varscan2
- DDX20 | c.1394C>G p.A465G | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV100862179; called by muse, mutect2, varscan2
- DEFB112 | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.763); catalogued as COSV100452147; called by muse, mutect2, varscan2
- DIAPH2 | c.1797A>T p.L599F | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs187696875, COSV100233025; called by muse, mutect2, varscan2
- DLGAP4 | c.584G>C p.R195P | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100211304; called by muse, mutect2, varscan2
- DNAH8 | c.3157A>T p.K1053* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV100545548; called by muse, mutect2, varscan2
- DNAH8 | c.3243G>T p.M1081I | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100545550; called by muse, varscan2
- DNAI2 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 136/379 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100209802; called by muse, mutect2, varscan2
- DPF3 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100818587, COSV63500254; called by muse, mutect2, varscan2
- DPPA2 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101524768, COSV72118254; called by muse, mutect2, varscan2
- EHD2 | c.1340C>A p.T447N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV99621964; called by muse, mutect2, varscan2
- ELAPOR1 | c.1594A>G p.K532E | Missense Mutation (SNP) | VAF 102/137 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV100884437; called by muse, mutect2, varscan2
- ENC1 | c.848T>A p.V283E | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1406021380, COSV100188067; called by muse, mutect2, varscan2
- EP300 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54327022; called by muse, mutect2, varscan2
- EPHA7 | c.1042A>T p.S348C | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); catalogued as COSV100993808; called by muse, mutect2, varscan2
- ERICH3 | c.3946G>T p.G1316W | Missense Mutation (SNP) | VAF 81/108 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100443805, COSV58622177; called by muse, mutect2, varscan2
- ERP27 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99844322; called by muse, mutect2, varscan2
- F5 | c.6364T>A p.W2122R | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889122; called by muse, mutect2, varscan2
- FAM120B | c.2018-2A>T p.X673_splice | Splice Site (SNP) | VAF 31/36 reads (86%) | catalogued as COSV99379433; called by muse, mutect2, varscan2
- FAM135B | c.2255C>A p.S752Y | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52748775, COSV99424279; called by muse, mutect2, varscan2
- FASLG | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs201780506, COSV100390499; called by muse, mutect2, varscan2
- FBXO22 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760473711, COSV100380572; called by muse, mutect2, varscan2
- FBXO8 | c.772+1G>T p.X258_splice | Splice Site (SNP) | VAF 26/31 reads (84%) | catalogued as COSV101183662; called by muse, mutect2, varscan2
- FGB | c.881G>T p.R294M | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100122449, COSV57417946; called by muse, mutect2, varscan2
- FLNB | c.5827A>G p.K1943E | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.41); PolyPhen benign (0.206); catalogued as COSV99913358; called by muse, mutect2, varscan2
- FLT1 | c.3971C>A p.P1324H | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99159271; called by muse, mutect2, varscan2
- FOXG1 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100486846; called by muse, mutect2, varscan2
- FSCB | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 101/170 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.263); catalogued as COSV100469367; called by muse, mutect2, varscan2
- FSHR | c.469A>T p.I157F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV100437248; called by muse, mutect2, varscan2
- GABRB3 | c.876C>A p.H292Q | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV100158842; called by muse, mutect2, varscan2
- GATA3 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV60520760, COSV60521164; called by muse, varscan2
- GCA | c.371G>C p.W124S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280576; called by muse, mutect2, varscan2
- GCA | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280579; called by muse, mutect2, varscan2
- GIN1 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 70/95 reads (74%) | catalogued as COSV101204336; called by muse, mutect2, varscan2
- GNG2 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV100087682; called by muse, mutect2, varscan2
- GOLGA3 | c.3732G>T p.E1244D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52630118, COSV99206208; called by muse, varscan2
- GON4L | c.251C>G p.T84S | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.138); catalogued as COSV99674391; called by muse, mutect2, varscan2
- GPR139 | c.896C>A p.T299K | Missense Mutation (SNP) | VAF 83/153 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as rs767531379, COSV58505724; called by muse, mutect2, varscan2
- GPR78 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV101223986; called by muse, mutect2, varscan2
- GRB7 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.155); catalogued as COSV100485519; called by muse, mutect2, varscan2
- GRID2 | c.1405G>C p.G469R | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99941276; called by muse, mutect2, varscan2
- GRIN3B | c.1748C>A p.A583E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52260688, COSV99312564; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1192T>C p.F398L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV99734771; called by muse, mutect2, varscan2
- GTPBP1 | c.1530G>T p.Q510H | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99323223; called by muse, mutect2, varscan2
- H1-2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.753); catalogued as rs781281855, COSV59190279, COSV59190466; called by muse, mutect2, varscan2
- HAS3 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99544408; called by muse, mutect2, varscan2
- HAUS5 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs747319351, COSV52547941; called by muse, mutect2
- HBB | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as CM112038, CM840028, COSV100092763, COSV58943287; called by muse, mutect2, varscan2
- HCN1 | c.2069C>A p.P690Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100300443; called by muse, mutect2, varscan2
- HCN1 | c.931T>C p.W311R | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100300445; called by muse, mutect2, varscan2
- HCN1 | c.434G>C p.W145S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100300446; called by muse, mutect2, varscan2
- HIVEP2 | c.6073G>T p.E2025* | Nonsense Mutation (SNP) | VAF 102/133 reads (77%) | catalogued as COSV99173605; called by muse, mutect2, varscan2
- HPX | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99793347; called by muse, mutect2, varscan2
- HSPB8 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV99931276; called by muse, mutect2, varscan2
- IFNA1 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99439898; called by muse, varscan2
- IGHV3-20 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as rs543741320; called by muse, varscan2
- INPPL1 | c.3364T>C p.S1122P | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99996276; called by muse, mutect2, varscan2
- INSC | c.597G>C p.R199S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as COSV101089217; called by muse, mutect2, varscan2
- IQCN | c.2806G>A p.G936S | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.682); catalogued as rs753958999, COSV100828286; called by muse, mutect2, varscan2
- ITGA5 | c.46C>A p.R16S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as COSV99516669; called by muse, varscan2
- ITGAE | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 151/266 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.198); catalogued as COSV99561050; called by muse, mutect2, varscan2
- ITGB4 | c.1783C>A p.H595N | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99564083; called by muse, mutect2, varscan2
- ITPRID1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100086496; called by muse, mutect2, varscan2
- JAG1 | c.3388G>A p.G1130R | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT tolerated (0.52); PolyPhen benign (0.289); catalogued as COSV99652951; called by muse, mutect2, varscan2
- KAT2A | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs868974836, COSV52425098; called by muse, mutect2, varscan2
- KCNA4 | c.1931C>A p.S644Y | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV100068977; called by muse, mutect2, varscan2
- KEAP1 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50263268; called by muse, mutect2, varscan2
- KMT2A | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100628931; called by muse, mutect2, varscan2
- KMT2B | c.4926G>T p.E1642D | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.228); catalogued as COSV99719717; called by muse, mutect2, varscan2
- KNL1 | c.4165C>T p.P1389S (on ENST00000346991 / NM_170589.5; = p.P1363S on NM_144508.5) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs972115072, COSV100706541; called by muse, mutect2, varscan2
- KNL1 | c.4481C>T p.S1494F (on ENST00000346991 / NM_170589.5; = p.S1468F on NM_144508.5) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV100706544; called by muse, mutect2, varscan2
- KPNA4 | c.1550A>T p.E517V | Missense Mutation (SNP) | VAF 76/336 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.302); catalogued as COSV100515181; called by muse, mutect2, varscan2
- KPNA4 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.119); catalogued as COSV100515182; called by muse, mutect2, varscan2
- KREMEN1 | c.107A>G p.N36S (on ENST00000407188; = p.N38S on NM_032045.5) | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs35199515; called by muse, mutect2, varscan2
- KYAT3 | c.652A>G p.N218D | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99556246; called by muse, mutect2, varscan2
- LAMC2 | c.3449G>A p.R1150H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs748464019, COSV99680047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC3 | c.1686C>G p.F562L | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as COSV100735990; called by muse, mutect2, varscan2
- LAMC3 | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as COSV100735922, COSV100735991; called by muse, mutect2, varscan2
- LCE1E | c.131G>T p.C44F | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100908550; called by muse, mutect2, varscan2
- LCE1F | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57670214; called by muse, mutect2, varscan2
- LNP1 | c.74G>T p.W25L | Missense Mutation (SNP) | VAF 92/321 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as COSV101051276; called by muse, mutect2, varscan2
- LONP2 | c.1036A>C p.M346L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99589240; called by muse, mutect2, varscan2
- LRP5 | c.3054A>C p.Q1018H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as COSV99592056; called by muse, mutect2, varscan2
- LRRC36 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.423); catalogued as COSV99338740; called by muse, mutect2, varscan2
- LSM5 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs1314018986, COSV99776399; called by muse, mutect2, varscan2
- LYST | c.5576C>T p.S1859F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV101089579; called by muse, mutect2, varscan2
- MAGEB18 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100305482, COSV57463695; called by muse, mutect2, varscan2
- MAGEC1 | c.1203G>T p.E401D | Missense Mutation (SNP) | VAF 224/255 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53578038, COSV99595775; called by muse, mutect2, varscan2
- MED25 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as COSV100457457; called by muse, mutect2, varscan2
- MEFV | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 60/230 reads (26%) | catalogued as COSV54823966, COSV99560910; called by muse, mutect2, varscan2
- MICAL1 | c.728A>G p.N243S | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs781457382, COSV100668588; called by muse, mutect2, varscan2
- MOGAT2 | c.599C>G p.T200R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as COSV99549580; called by muse, mutect2, varscan2
- MST1R | c.2851G>T p.D951Y | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV56573173; called by muse, mutect2, varscan2
- MUC17 | c.6456A>C p.Q2152H | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100073460; called by muse, mutect2
- MUC17 | c.9673A>G p.T3225A | Missense Mutation (SNP) | VAF 112/384 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as COSV100073463; called by muse, mutect2, varscan2
- MYH10 | c.2549A>T p.Q850L | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99345323; called by muse, mutect2, varscan2
- MYH2 | c.2042C>A p.P681H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99819646, COSV99820241; called by muse, mutect2, varscan2
- MYO18A | c.3191G>T p.R1064L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.069); catalogued as COSV100572323, COSV62864717; called by muse, mutect2, varscan2
- MYO1D | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV100554324; called by muse, varscan2
- MYO1D | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100554328; called by muse, varscan2
- NACC1 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs778872897, COSV99457027; called by muse, mutect2, varscan2
- NCAM2 | c.1793C>A p.S598Y | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99523199; called by muse, mutect2, varscan2
- NDUFS7 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs925435610, COSV99282809; called by muse, mutect2, varscan2
- NEO1 | c.2932C>T p.Q978* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV99982138; called by muse, mutect2, varscan2
- NEU3 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99579451; called by muse, mutect2, varscan2
- NEU4 | c.223G>C p.G75R (on ENST00000391969 / NM_001167602.3; = p.G87R on NM_080741.4) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV100372040; called by muse, varscan2
- NFKBIB | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100548383; called by muse, mutect2, varscan2
- NLRP1 | c.1688C>A p.P563Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as COSV99334270; called by muse, mutect2, varscan2
- NLRP12 | c.1207G>C p.V403L | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs765948822, COSV100145325, COSV60743430, COSV60753163; called by muse, mutect2, varscan2
- NLRP12 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60746255; called by muse, mutect2, varscan2
- NLRP7 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV100052714; called by muse, mutect2, varscan2
- NLRP8 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV52587976, COSV99405347, COSV99406131; called by muse, varscan2
- NPHS1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100799910; called by muse, mutect2, varscan2
- NPY2R | c.682T>C p.Y228H | Missense Mutation (SNP) | VAF 59/82 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1560765420, COSV100279736; called by muse, mutect2, varscan2
- NUP133 | c.975G>A p.W325* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV99772962; called by muse, mutect2, varscan2
- NXPH2 | c.173T>A p.L58Q | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99740723; called by muse, mutect2, varscan2
- OLFML2B | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV99668481; called by muse, mutect2, varscan2
- OR11H12 | c.941C>A p.A314E | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs761025229, COSV101612495; called by muse, mutect2, varscan2
- OR1C1 | c.889A>G p.M297V | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs1434759779, COSV101376231; called by muse, mutect2, varscan2
- OR2C3 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as COSV100825708; called by muse, mutect2, varscan2
- OR2T1 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100822314; called by muse, mutect2, varscan2
- OR2T27 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100788275; called by mutect2, varscan2
- OR4A15 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100124119; called by muse, mutect2, varscan2
- OR51B2 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.279); catalogued as COSV100173284; called by muse, mutect2, varscan2
- OR5L2 | c.374C>G p.A125G | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101004326, COSV101004417; called by muse, mutect2
- OR5M10 | c.6G>T p.L2F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV73242416; called by muse, varscan2
- OR5P2 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1288107463, COSV100271357; called by muse, mutect2, varscan2
- OR7D4 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100432746; called by muse, mutect2, varscan2
- OR8K5 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100537220, COSV57891348; called by muse, mutect2, varscan2
- OS9 | c.518A>G p.Q173R | Missense Mutation (SNP) | VAF 89/159 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232813; called by muse, mutect2, varscan2
- PALB2 | c.420del p.K140Nfs*37 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as COSV99848024; called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.361T>A p.F121I (on ENST00000374531 / NM_001037293.2; = p.F119I on NM_007203.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100093161; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2296G>T p.A766S (on ENST00000259318 / NM_001136562.3; = p.A997S on NM_007203.5) | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99395260; called by muse, mutect2, varscan2
- PARP8 | c.1385T>C p.I462T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.344); catalogued as COSV99891655; called by muse, mutect2, varscan2
- PCDH11X | c.476C>A p.T159N | Missense Mutation (SNP) | VAF 54/65 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100007062; called by muse, mutect2, varscan2
- PCDHB16 | c.1696C>A p.Q566K | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.39); catalogued as COSV99502113; called by muse, mutect2, varscan2
- PCLO | c.451A>T p.S151C | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100433164; called by muse, mutect2, varscan2
- PDK1 | c.1057G>C p.A353P | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99961312; called by muse, mutect2, varscan2
- PEX5 | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.555); catalogued as COSV99870959; called by muse, mutect2, varscan2
- PEX5L | c.22-1del p.X8_splice | Splice Site (DEL) | VAF 34/79 reads (43%) | catalogued as COSV99028987; called by mutect2, pindel, varscan2
- PHACTR1 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); catalogued as COSV100277167; called by muse, mutect2
- PHACTR4 | c.242G>A p.R81K (on ENST00000373839 / NM_001350159.2; = p.R91K on NM_023923.4) | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.875); catalogued as COSV100868458; called by muse, mutect2, varscan2
- PHF2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100823185, COSV100823197; called by muse, mutect2, varscan2
- PHIP | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs185895794, COSV51504508, COSV99245359; called by muse, mutect2, varscan2
- PIK3C3 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 86/123 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1444149604, COSV100011002; called by muse, mutect2, varscan2
- PKM | c.1579G>C p.V527L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100064854; called by muse, mutect2, varscan2
- PKP3 | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV100520865; called by muse, mutect2, varscan2
- PLA2G7 | c.888T>A p.D296E | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99221391; called by muse, mutect2, varscan2
- PPARGC1A | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99337972; called by muse, mutect2, varscan2
- PPHLN1 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99871353; called by muse, mutect2, varscan2
- PPP3R2 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV100701524, COSV62456409; called by muse, mutect2, varscan2
- PRDM10 | c.2167G>C p.D723H | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV100456807, COSV58800345; called by muse, mutect2, varscan2
- PRDM14 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as COSV99400211; called by muse, mutect2, varscan2
- PREX1 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100906372; called by muse, mutect2, varscan2
- PRR23B | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 33/128 reads (26%) | catalogued as COSV100272090; called by muse, mutect2, varscan2
- PRRC2B | c.6023G>A p.S2008N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV57645918; called by muse, mutect2, varscan2
- PRUNE2 | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100944638; called by muse, mutect2, varscan2
- PTPN6 | c.871G>T p.G291* | Nonsense Mutation (SNP) | VAF 38/100 reads (38%) | catalogued as COSV100017123; called by muse, mutect2, varscan2
- PTPRG | c.2241G>T p.L747F | Missense Mutation (SNP) | VAF 84/114 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55630796, COSV55665018, COSV99875129; called by muse, mutect2, varscan2
- RABEP2 | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100707063; called by muse, mutect2, varscan2
- RFPL1 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV100585765; called by muse, mutect2, varscan2
- RGS7 | c.130C>A p.R44S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RNF144A | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.287); catalogued as COSV100305710, COSV100305790; called by muse, mutect2, varscan2
- RNF214 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100326723; called by muse, mutect2, varscan2
- ROR2 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100995845; called by muse, mutect2, varscan2
- RPL6 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs372781987, COSV99176137; called by muse, mutect2, varscan2
- RPL6 | c.698T>A p.F233Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99176138; called by muse, mutect2, varscan2
- RRAGD | c.953T>G p.I318S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV100784569; called by muse, mutect2, varscan2
- RRBP1 | c.2803G>C p.E935Q (on ENST00000377813 / NM_001365613.2; = p.E502Q on NM_004587.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.95); catalogued as COSV99854088; called by muse, mutect2, varscan2
- RYR1 | c.12519C>A p.F4173L | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100615823; called by muse, varscan2
- RYR1 | c.12520C>T p.R4174C | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1299960881, COSV100615825; called by muse, varscan2
- RYR2 | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1379190155, COSV63676788; called by muse, mutect2, varscan2
- RYR3 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66810001; called by muse, mutect2, varscan2
- RYR3 | c.9571A>T p.M3191L (on ENST00000389232; = p.M3192L on NM_001036.6) | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV101212863; called by muse, varscan2
- SATL1 | c.520C>A p.P174T (on ENST00000395409; = p.P361T on NM_001012980.2) | Missense Mutation (SNP) | VAF 63/72 reads (88%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60578303; called by muse, mutect2, varscan2
- SCGB1D2 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV99793570; called by muse, mutect2, varscan2
- SCN7A | c.2186G>A p.S729N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.462); catalogued as COSV101313245; called by muse, mutect2, varscan2
- SECISBP2L | c.563G>T p.R188M | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1322422461, COSV99960399; called by muse, mutect2, varscan2
- SF3B4 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV54965386, COSV99641190; called by muse, mutect2, varscan2
- SLC25A48 | c.420C>T p.D140= | Splice Region (SNP) | VAF 15/23 reads (65%) | catalogued as rs777873378, COSV99192030; called by muse, mutect2, varscan2
- SLC2A14 | c.1184T>A p.L395* | Nonsense Mutation (SNP) | VAF 44/94 reads (47%) | catalogued as COSV100533825; called by muse, mutect2, varscan2
- SLC4A3 | c.3608G>T p.R1203M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as COSV99812873; called by muse, mutect2, varscan2
- SLCO1B1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV99918553; called by muse, mutect2, varscan2
- SLFN13 | c.1837A>G p.M613V | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV99540027; called by muse, mutect2, varscan2
- SMPD4 | c.1340G>T p.W447L (on ENST00000409031 / NM_017951.4; = p.W418L on NM_017751.4) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100302507; called by muse, mutect2, varscan2
- SMTN | c.1371G>T p.M457I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100294403; called by muse, mutect2, varscan2
- SPEF2 | c.3749A>C p.E1250A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100607547; called by muse, mutect2, varscan2
- SPHKAP | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 28/126 reads (22%) | catalogued as COSV100764139; called by muse, mutect2, varscan2
- SPNS1 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV57956144; called by muse, mutect2, varscan2
- SPRR2B | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV100482298; called by muse, varscan2
- SPTBN4 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs138314115, COSV58944722; called by muse, mutect2, varscan2
- SRPRA | c.120A>T p.E40D | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV99702831; called by muse, mutect2, varscan2
- ST8SIA3 | c.1003C>G p.P335A | Missense Mutation (SNP) | VAF 25/32 reads (78%) | PolyPhen possibly damaging (0.883); catalogued as COSV100129547; called by muse, mutect2, varscan2
- ST8SIA3 | c.1004C>A p.P335Q | Missense Mutation (SNP) | VAF 25/32 reads (78%) | PolyPhen probably damaging (0.986); catalogued as COSV100129548, COSV60655252; called by muse, mutect2, varscan2
- STAB2 | c.989A>T p.N330I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101185994; called by muse, mutect2, varscan2
- STARD10 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761639628, COSV100600447; called by muse, mutect2, varscan2
- STAT6 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 47/154 reads (31%) | catalogued as COSV100273337; called by muse, mutect2, varscan2
- STX2 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99892900; called by muse, mutect2, varscan2
- STXBP5L | c.2201A>G p.D734G | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV99874410; called by muse, mutect2, varscan2
- SUPT6H | c.4994A>G p.K1665R | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV99972727; called by muse, mutect2, varscan2
- TBC1D23 | c.2050A>T p.K684* (on ENST00000394144 / NM_001199198.3; = p.K669* on NM_018309.5) | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100792614; called by muse, mutect2
- TBC1D8 | c.2357A>G p.H786R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV100964485; called by muse, mutect2, varscan2
- TBL2 | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as COSV99979627; called by muse, mutect2, varscan2
- TG | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV55080990, COSV99601042; called by muse, mutect2, varscan2
- THRAP3 | c.2269dup p.T757Nfs*6 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | catalogued as rs1443424346; called by mutect2, pindel, varscan2
- TLL2 | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100780308; called by muse, mutect2, varscan2
- TMEM165 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773310050, COSV63529155; called by mutect2, varscan2
- TMEM184A | c.1148C>G p.P383R | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99868328; called by muse, mutect2, varscan2
- TNIK | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV99457496; called by muse, mutect2, varscan2
- TNR | c.1957C>A p.L653M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99056744; called by muse, mutect2, varscan2
- TNR | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99689799; called by muse, mutect2, varscan2
- TOGARAM1 | c.4534C>T p.Q1512* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | catalogued as COSV100818062; called by muse, mutect2, varscan2
- TRIM14 | c.37del p.R13Gfs*64 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as COSV58356453; called by mutect2, varscan2
- TRIM51 | c.1145G>A p.C382Y | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99792643; called by muse, mutect2, varscan2
- TTN | c.23971C>A p.P7991T (on ENST00000591111; = p.P7064T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/89 reads (56%) | PolyPhen benign (0.14); catalogued as COSV100615014; called by muse, mutect2, varscan2
- TXNDC2 | c.1557C>G p.I519M (on ENST00000306084 / NM_001098529.2; = p.I452M on NM_032243.6) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100046195; called by muse, mutect2, varscan2
- UHRF2 | c.126C>A p.C42* | Nonsense Mutation (SNP) | VAF 17/20 reads (85%) | catalogued as COSV99436763; called by muse, varscan2
- USH2A | c.9724G>A p.A3242T | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs373965999, COSV56435142; called by muse, mutect2, varscan2
- USH2A | c.9341C>A p.P3114Q | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100235614; called by muse, varscan2
- USP19 | c.2671A>G p.T891A | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as COSV100026194; called by muse, mutect2, varscan2
- UXS1 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99308297; called by muse, mutect2, varscan2
- VILL | c.2146C>A p.H716N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99378909; called by muse, mutect2, varscan2
- VPS13A | c.8636G>A p.G2879D | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100652881; called by muse, mutect2, varscan2
- YIF1A | c.428-2A>T p.X143_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100268448; called by muse, mutect2, varscan2
- YLPM1 | c.2956G>T p.G986C | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.948); catalogued as COSV99459807; called by muse, mutect2, varscan2
- YTHDC2 | c.1828A>G p.M610V | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV99363374; called by muse, mutect2, varscan2
- ZBED2 | c.51A>T p.K17N | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV51913318, COSV99342922; called by muse, mutect2, varscan2
- ZBTB16 | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100251558; called by muse, mutect2, varscan2
- ZNF154 | c.538T>A p.W180R | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.142); catalogued as COSV101377513; called by muse, mutect2, varscan2
- ZNF572 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.081); catalogued as rs772706704, COSV100073970; called by muse, mutect2, varscan2
- ZNF609 | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100441110; called by muse, mutect2, varscan2
- ZNF609 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100441112; called by muse, mutect2, varscan2
- ZNF653 | c.1040G>C p.G347A | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99542143; called by muse, mutect2, varscan2
- ZNF804B | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV100303997; called by muse, mutect2, varscan2
- ZNF831 | c.687G>T p.R229S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100926051, COSV64046073; called by muse, mutect2, varscan2
- ZNF831 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV100926052; called by muse, mutect2, varscan2
- ACACA | c.6892G>T p.A2298S | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- CACUL1 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CD2 | c.361del p.I121Yfs*4 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- GAS2L2 | c.1001G>T p.R334M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GCDH | c.499del p.Q167Sfs*57 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | called by mutect2, pindel, varscan2
- IGHV1-24 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 207/312 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, varscan2
- KEAP1 | c.1764_1769del p.D589_T590del | In Frame Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- NBAS | c.3913del p.Q1305Rfs*3 | Frame Shift Del (DEL) | VAF 17/167 reads (10%) | called by mutect2, pindel, varscan2
- NDUFV1 | c.323del p.G108Afs*8 | Frame Shift Del (DEL) | VAF 49/122 reads (40%) | called by mutect2, pindel, varscan2
- POTEA | c.467C>G p.T156S | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2
- PTPN14 | c.3552_3558del p.R1185Ffs*60 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- RAB3IP | c.708dup p.Q237Tfs*10 (on ENST00000550536 / NM_175623.4; = p.Q221Tfs*10 on NM_022456.5) | Frame Shift Ins (INS) | VAF 26/49 reads (53%) | called by mutect2, varscan2
- SOCS7 | c.1252+1G>A p.X418_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | called by muse, varscan2
- TPM4 | c.96dup p.E33* | Frame Shift Ins (INS) | VAF 20/46 reads (43%) | called by mutect2, pindel
- TRAV12-3 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TRBV30 | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- VWA3B | c.179del p.G60Dfs*39 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | called by mutect2, varscan2
- ABCC3 | c.3603C>T p.F1201= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as rs760337449, COSV53322193; called by muse, mutect2, varscan2
- ABCG1 | c.609G>T p.A203= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as rs201037860, COSV100494217; called by muse, mutect2, varscan2
- AHNAK2 | c.3630C>T p.D1210= | Silent (SNP) | VAF 68/380 reads (18%) | catalogued as COSV100317640; called by muse, varscan2
- ARMCX5 | c.198C>G p.T66= | Silent (SNP) | VAF 56/60 reads (93%) | catalogued as rs769413727, COSV99863409; called by muse, mutect2, varscan2
- C11orf80 | c.1161A>G p.A387= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV60930739; called by muse, mutect2, varscan2
- C6 | c.12C>G p.R4= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99667148; called by muse, mutect2
- CABP5 | c.285C>A p.P95= | Silent (SNP) | VAF 70/123 reads (57%) | catalogued as COSV99506559; called by muse, mutect2, varscan2
- CCDC40 | c.2094G>C p.L698= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV100884254, COSV66479175; called by muse, mutect2, varscan2
- CCNB1 | c.579G>T p.L193= | Silent (SNP) | VAF 74/100 reads (74%) | catalogued as COSV56510292, COSV99841310; called by muse, mutect2, varscan2
- CLCNKA | c.606G>T p.V202= | Silent (SNP) | VAF 44/66 reads (67%) | catalogued as COSV100510119, COSV58893877; called by muse, mutect2, varscan2
- CLYBL | c.672C>T p.Y224= | Silent (SNP) | VAF 80/117 reads (68%) | catalogued as rs145178349; called by muse, mutect2, varscan2
- COL3A1 | c.411C>T p.P137= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100483087; called by muse, varscan2
- CR2 | c.2955A>T p.I985= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100889649; called by muse, mutect2, varscan2
- DNAH3 | c.9351C>T p.N3117= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as rs200801494, COSV99767732; called by muse, mutect2, varscan2
- DNAJA3 | c.912G>C p.V304= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99276705; called by muse, mutect2, varscan2
- DPPA2 | c.756C>A p.T252= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as COSV101524767; called by muse, mutect2, varscan2
- EMSY | c.237T>C p.I79= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100595726; called by muse, mutect2
- FBXL18 | c.621G>A p.T207= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101212076; called by muse, mutect2, varscan2
- GIMAP5 | c.708G>T p.G236= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100500250; called by muse, mutect2, varscan2
- HID1 | c.2322C>A p.V774= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100172843; called by muse, mutect2, varscan2
- HMX2 | c.138C>T p.S46= | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as rs761469225, COSV100378771; called by muse, mutect2, varscan2
- IGF1R | c.666G>A p.R222= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99151460, COSV99163106; called by mutect2, varscan2
- IGHV3-49 | c.90G>A p.L30= | Silent (SNP) | VAF 98/152 reads (64%) | catalogued as rs782347952; called by muse, mutect2, varscan2
- IGKV1-27 | c.237G>T p.G79= | Silent (SNP) | VAF 70/215 reads (33%) | called by muse, mutect2, varscan2
- ISY1 | c.741G>T p.S247= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99860816; called by muse, mutect2, varscan2
- ITPRID1 | c.1932C>A p.P644= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV100086498; called by muse, mutect2, varscan2
- KCNA6 | c.1122G>A p.R374= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV99768661; called by muse, mutect2, varscan2
- KCNJ9 | c.246C>A p.I82= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100927752; called by muse, mutect2, varscan2
- LRSAM1 | c.993G>A p.T331= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs368674859; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEB6B | c.840T>C p.N280= | Silent (SNP) | VAF 36/111 reads (32%) | called by muse, mutect2, varscan2
- MED12L | c.6102T>C p.S2034= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as rs147294855; called by muse, mutect2, varscan2
- MMP2 | c.1560T>C p.I520= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs137912216, COSV99527814; called by muse, mutect2, varscan2
- MOCS1 | c.1467A>G p.G489= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV99225784; called by muse, mutect2, varscan2
- MRPS34 | c.528A>T p.A176= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV99168920; called by muse, mutect2, varscan2
- MYH14 | c.4239G>T p.R1413= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99222824; called by muse, mutect2, varscan2
- MYRF | c.2569C>T p.L857= (on ENST00000278836 / NM_001127392.3; = p.L822= on NM_013279.4) | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV99607145; called by muse, mutect2, varscan2
- NLRP3 | c.549G>A p.Q183= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100275357, COSV100276117; called by muse, mutect2, varscan2
- NPAP1 | c.2961G>A p.G987= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV100275379, COSV100275458; called by muse, mutect2, varscan2
- OPN1LW | c.798G>A p.V266= | Silent (SNP) | VAF 123/145 reads (85%) | catalogued as COSV100885040; called by muse, mutect2, varscan2
- OR10Q1 | c.657C>T p.I219= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs751229319, COSV100372291; called by muse, mutect2, varscan2
- OR51E1 | c.447G>T p.V149= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV101211514; called by muse, mutect2, varscan2
- OR51G1 | c.315C>T p.F105= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV58969176; called by muse, mutect2, varscan2
- OR52N5 | c.570C>T p.H190= | Silent (SNP) | VAF 52/59 reads (88%) | catalogued as COSV100399702; called by muse, mutect2, varscan2
- OR5AC2 | c.303C>A p.T101= | Silent (SNP) | VAF 109/398 reads (27%) | catalogued as COSV100684394; called by muse, mutect2, varscan2
- OR5W2 | c.663C>A p.I221= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100747639; called by muse, varscan2
- OR8D1 | c.609G>A p.A203= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs148861414; called by muse, mutect2, varscan2
- PLEKHM3 | c.1227G>A p.V409= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV101216602; called by muse, mutect2, varscan2
- PLPP5 | c.279C>T p.A93= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100395341; called by muse, mutect2, varscan2
- PLXNB1 | c.2604C>A p.L868= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99602887; called by muse, varscan2
- PPP3R2 | c.387C>A p.L129= | Silent (SNP) | VAF 65/83 reads (78%) | catalogued as COSV100701525; called by muse, mutect2, varscan2
- PRPS2 | c.69G>A p.L23= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV101028362; called by muse, mutect2, varscan2
- RASGRP3 | c.354C>T p.I118= | Silent (SNP) | VAF 38/228 reads (17%) | catalogued as rs745628834, COSV101274762; called by muse, mutect2, varscan2
- SCN5A | c.51A>G p.T17= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as COSV100028382; called by muse, mutect2, varscan2
- SCUBE3 | c.1125T>C p.T375= | Silent (SNP) | VAF 87/230 reads (38%) | catalogued as COSV99234519; called by muse, mutect2, varscan2
- SESN2 | c.471C>A p.R157= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99455762; called by muse, mutect2, varscan2
- SGPP1 | c.567G>T p.P189= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99905853; called by muse, mutect2, varscan2
- SLAMF6 | c.897A>C p.T299= (on ENST00000368057 / NM_001184714.2; = p.T298= on NM_052931.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100924890; called by muse, mutect2, varscan2
- SLC13A1 | c.1683T>A p.G561= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99520974; called by muse, mutect2, varscan2
- SLC1A6 | c.411G>A p.V137= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99693786; called by muse, mutect2, varscan2
- SLC9A5 | c.825C>T p.V275= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100237324; called by muse, mutect2
- SUPT5H | c.1014G>A p.R338= | Silent (SNP) | VAF 66/118 reads (56%) | catalogued as COSV100782083, COSV63241811; called by muse, mutect2, varscan2
- TBC1D23 | c.2049T>C p.T683= (on ENST00000394144 / NM_001199198.3; = p.T668= on NM_018309.5) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100792611, COSV61370029; called by muse, mutect2
- TCP11L2 | c.1413G>A p.Q471= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV100135371; called by muse, mutect2, varscan2
- TDRD6 | c.4896T>C p.F1632= | Silent (SNP) | VAF 78/160 reads (49%) | catalogued as COSV100287681; called by muse, mutect2, varscan2
- TMEM30A | c.651C>T p.P217= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs1377893835, COSV100034914; called by muse, mutect2, varscan2
- TTC7A | c.1056C>T p.S352= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs887426063, COSV55410701, COSV99766478; called by muse, mutect2
- TTN | c.42990T>C p.G14330= (on ENST00000591111; = p.G6906= on NM_003319.4) | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as COSV100615010; called by muse, mutect2, varscan2
- VAT1L | c.996G>A p.R332= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs764275688, COSV100213383; called by muse, mutect2
- VGLL2 | c.288C>T p.S96= | Silent (SNP) | VAF 47/62 reads (76%) | catalogued as COSV100409929; called by muse, mutect2, varscan2
- VPS13A | c.4917A>G p.P1639= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100652879; called by muse, mutect2, varscan2
- XIRP2 | c.5805C>A p.V1935= (on ENST00000628543; = p.V2110= on NM_152381.6) | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99743309; called by muse, mutect2, varscan2
- XRN2 | c.1815A>T p.A605= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as COSV101018362; called by muse, varscan2
- ZMIZ2 | c.2571T>A p.G857= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as COSV54806012; called by muse, mutect2, varscan2
- ZNF491 | c.810T>A p.P270= | Silent (SNP) | VAF 40/74 reads (54%) | catalogued as COSV100021906; called by muse, mutect2, varscan2
- ZNF556 | c.1227G>T p.G409= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV100298753; called by muse, mutect2, varscan2
- ZNF664 | c.735C>T p.H245= | Silent (SNP) | VAF 11/142 reads (8%) | catalogued as COSV100544490; called by muse, mutect2
- ZNF700 | c.180G>A p.L60= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as COSV99583545; called by muse, mutect2, varscan2
- ABHD3 | c.555+369C>A | Intron (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100004399; called by muse, mutect2, varscan2
- CABP1 | c.655-9196G>A | Intron (SNP) | VAF 15/94 reads (16%) | catalogued as COSV99974699; called by muse, mutect2, varscan2
- CFAP46 | c.966+146C>A | Intron (SNP) | VAF 16/25 reads (64%) | catalogued as COSV100886549; called by muse, mutect2, varscan2
- KHDC4 | c.-1C>T | 5'UTR (SNP) | VAF 21/52 reads (40%) | catalogued as rs750213834, COSV100850813, COSV64164767; called by muse, mutect2, varscan2
- TREML2 | c.-89T>C | 5'UTR (SNP) | VAF 20/43 reads (47%) | catalogued as COSV101530172; called by muse, mutect2, varscan2
- ZNF99 | c.*555C>A | 3'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as COSV101233838; called by muse, mutect2, varscan2
